Somatic mutation profile of tumor specimen C3L-07144-01 (aliquot CPT0461380006) from CPTAC case C3L-07144, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.3 years (24,956 days).
Specimen C3L-07144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55db11b0-5ac1-42ee-981b-a3d8707144b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07144-71 (Blood Derived Normal), aliquot CPT0460030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc23e6a0-959b-4e45-ae5d-2bc957b76c5e

The open-access MAF lists 166 somatic variants for this specimen: 127 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 36, Nonsense Mutation 6, Frame Shift Del 4, Splice Region 2, 5'UTR 2, Frame Shift Ins 2, In Frame Del 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 127/206 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; called by muse, mutect2, varscan2
- ADPRH | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.75); catalogued as rs1481472656; called by muse, mutect2, varscan2
- AMPD3 | c.514C>T p.R172C (on ENST00000396553 / NM_001025389.2; = p.R181C on NM_000480.3) | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs750786612; called by muse, mutect2, varscan2
- ANG | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs770840869, COSV59011594; called by muse, mutect2, varscan2
- ARHGEF3 | c.1355del p.L452Cfs*17 | Frame Shift Del (DEL) | VAF 82/322 reads (25%) | catalogued as rs1445194572; called by mutect2, pindel, varscan2
- BPIFB4 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 110/472 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV64951249; called by mutect2, varscan2
- BRINP3 | c.1799A>C p.K600T | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as COSV66517281; called by muse, mutect2, varscan2
- CADM2 | c.1189G>T p.G397* (on ENST00000407528 / NM_001167674.2; = p.G399* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 72/193 reads (37%) | catalogued as COSV67371870; called by muse, mutect2, varscan2
- CAMK1D | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as rs765682396, COSV66606122; called by muse, mutect2, varscan2
- CCDC59 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1375014726; called by muse, mutect2, varscan2
- COL15A1 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568399322, COSV66641303; called by muse, mutect2, varscan2
- CYFIP2 | c.1280G>A p.C427Y | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59054294; called by muse, mutect2, varscan2
- DNAJA1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV104401191; called by muse, mutect2, varscan2
- EHD2 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 132/501 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); catalogued as rs367574070; called by muse, mutect2, varscan2
- FAM114A2 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs144985973; called by muse, mutect2, varscan2
- FDCSP | c.93C>T p.I31= | Splice Region (SNP) | VAF 8/222 reads (4%) | catalogued as COSV58765437; called by muse, mutect2
- GMNC | c.540A>C p.Q180H | Missense Mutation (SNP) | VAF 96/421 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV101504369; called by muse, mutect2, varscan2
- GRIK1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774769899, COSV58709993; called by muse, mutect2, varscan2
- GSDME | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 84/491 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV61650954; called by muse, mutect2, varscan2
- HNRNPL | c.1450C>G p.R484G | Missense Mutation (SNP) | VAF 124/423 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55492265; called by muse, mutect2, varscan2
- IPO13 | c.822-1G>A p.X274_splice | Splice Site (SNP) | VAF 50/165 reads (30%) | catalogued as COSV100961361; called by mutect2, varscan2
- IRGC | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs758334834, COSV54982707; called by muse, mutect2, varscan2
- KCNH5 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs771253745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMX1B | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.139); catalogued as rs1241241362; called by muse, mutect2, varscan2
- MAGEB18 | c.498A>C p.E166D | Missense Mutation (SNP) | VAF 126/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57463531; called by muse, mutect2, varscan2
- MBTD1 | c.902G>C p.R301P | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64504395; called by muse, mutect2, varscan2
- MED12 | c.5146C>T p.R1716* | Nonsense Mutation (SNP) | VAF 143/314 reads (46%) | catalogued as COSV61360875; called by muse, mutect2, varscan2
- METTL25 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV50259255; called by muse, mutect2, varscan2
- NME8 | c.1435G>C p.D479H | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV99553156; called by muse, mutect2
- NTRK3 | c.2237A>T p.K746M (on ENST00000360948 / NM_001012338.2; = p.K732M on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62295703, COSV62301322; called by muse, mutect2, varscan2
- OR8U1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 106/750 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.651); catalogued as rs537232927, COSV100163763; called by muse, mutect2, varscan2
- PCBP3 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 89/471 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs778499516; called by muse, mutect2, varscan2
- PCDHAC2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs1281739668; called by muse, mutect2
- PPP6R3 | c.2497G>A p.A833T (on ENST00000393800 / NM_001352375.2; = p.A753T on NM_018312.5) | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs748446630, COSV55723101; called by muse, mutect2, varscan2
- PTPRU | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 14/391 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1200535287; called by muse, mutect2
- RALBP1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as rs751698054, COSV50035016; called by muse, mutect2, varscan2
- RWDD3 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.437); catalogued as rs1453021161, COSV55721713; called by muse, mutect2, varscan2
- SACS | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 103/589 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1156265936; called by muse, mutect2, varscan2
- SCAF4 | c.3032A>G p.N1011S | Missense Mutation (SNP) | VAF 130/530 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.274); catalogued as rs1337437766; called by muse, varscan2
- SEMA6D | c.1947A>T p.E649D (on ENST00000316364 / NM_153618.2; = p.E587D on NM_020858.2) | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV60371874, COSV60373482, COSV60380284; called by muse, mutect2, varscan2
- SERPINB9 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 114/589 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.145); catalogued as COSV66233361; called by muse, mutect2, varscan2
- SPATA6 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 122/323 reads (38%) | catalogued as COSV100893063, COSV64057598; called by muse, mutect2, varscan2
- SPDYE3 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.12); catalogued as rs1459749139; called by muse, mutect2, varscan2
- TAF8 | c.492G>T p.T164= | Splice Region (SNP) | VAF 60/272 reads (22%) | catalogued as COSV65895695; called by muse, mutect2, varscan2
- TRIM64 | c.1130dup p.L377Ffs*11 | Frame Shift Ins (INS) | VAF 110/256 reads (43%) | catalogued as rs1021264718; called by mutect2, varscan2
- TXNL1 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99469424, COSV99469956; called by muse, mutect2
- UBQLN3 | c.337A>T p.S113C | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV61164436; called by muse, mutect2, varscan2
- UNC13C | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768743988, COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- UTP20 | c.7883G>A p.R2628Q | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs764421472, COSV55373884; called by muse, mutect2, varscan2
- ZFP30 | c.758_763del p.V253_R254del | In Frame Del (DEL) | VAF 82/442 reads (19%) | catalogued as rs755078692; called by pindel, varscan2
- ACTA1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 20/580 reads (3%) | called by muse, mutect2
- ADAMTS12 | c.1301A>C p.K434T | Missense Mutation (SNP) | VAF 64/311 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ADGRB2 | c.4499G>A p.S1500N (on ENST00000373658 / NM_001364857.2; = p.S1499N on NM_001294335.2) | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ADGRE1 | c.1957C>T p.L653F | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AGBL1 | c.2569C>G p.L857V | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ALG5 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD18B | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 182/1551 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ANKRD30A | c.4123A>C p.N1375H (on ENST00000611781; = p.N1319H on NM_052997.2) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANKRD30B | c.1208C>G p.T403R | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ARSL | c.1583C>G p.P528R | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ASCC3 | c.5383T>A p.L1795M | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BACH1 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- C9orf40 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 76/326 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.237); called by mutect2, varscan2
- CADM3 | c.917G>A p.G306D (on ENST00000368125 / NM_001127173.3; = p.G340D on NM_021189.5) | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD2BP2 | c.670_689del p.R224Gfs*23 | Frame Shift Del (DEL) | VAF 102/351 reads (29%) | called by mutect2, pindel, varscan2
- CEP164 | c.3155A>G p.N1052S | Missense Mutation (SNP) | VAF 131/251 reads (52%) | SIFT tolerated (0.88); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DBNDD1 | c.283_303del p.S95_N101del (on ENST00000002501 / NM_001042610.3; = p.S115_N121del on NM_024043.3) | In Frame Del (DEL) | VAF 53/223 reads (24%) | called by mutect2, pindel, varscan2
- DCST2 | c.123_130del p.L42Afs*23 | Frame Shift Del (DEL) | VAF 320/454 reads (70%) | called by mutect2, pindel, varscan2
- DEFB121 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAH8 | c.4415_4416insC p.K1472Nfs*9 | Frame Shift Ins (INS) | VAF 42/266 reads (16%) | called by mutect2, pindel, varscan2
- DUS3L | c.979T>A p.F327I | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, varscan2
- EPHA7 | c.2351A>T p.E784V | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- F2RL3 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 107/312 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FBXO28 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 122/530 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRS3 | c.295A>G p.N99D | Missense Mutation (SNP) | VAF 175/388 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- FRY | c.2315T>C p.I772T | Missense Mutation (SNP) | VAF 91/441 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- GET1 | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 72/400 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRIA3 | c.4del p.A2? | Frame Shift Del (DEL) | VAF 114/150 reads (76%) | called by mutect2, pindel*, varscan2
- GRIP2 | c.325G>A p.E109K (on ENST00000619221; = p.E12K on NM_001080423.4) | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- GRM5 | c.73A>T p.R25W | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HSFX2 | c.175T>G p.L59V | Missense Mutation (SNP) | VAF 166/502 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGKV2D-30 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2
- INF2 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IPO11 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KIAA1755 | c.3296G>C p.G1099A | Missense Mutation (SNP) | VAF 127/518 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2
- KIF18A | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF24 | c.1121G>T p.R374I | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- KL | c.2185G>C p.A729P | Missense Mutation (SNP) | VAF 105/576 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- KLF13 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT82 | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 142/351 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA2 | c.1751G>C p.W584S | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTK | c.1162G>C p.D388H | Missense Mutation (SNP) | VAF 137/344 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- MDGA1 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 197/508 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MLF1 | c.281G>C p.G94A | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MTMR6 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- MTRR | c.899T>G p.V300G (on ENST00000264668; = p.V273G on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- MUC17 | c.10126G>A p.E3376K | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MYCBP2 | c.3947C>T p.T1316I (on ENST00000357337; = p.T1354I on NM_015057.5) | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 131/529 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- NRG1 | c.707A>C p.E236A (on ENST00000405005 / NM_013964.5; = p.E241A on NM_013956.5) | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRN1 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR13C8 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1D2 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 164/271 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR52J3 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OVCH1 | c.2083T>C p.S695P | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDH9 | c.1046C>A p.T349N | Missense Mutation (SNP) | VAF 76/561 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRKCG | c.674A>T p.E225V | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- PURB | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBMXL2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 98/373 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- SIM2 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SKOR1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC35B1 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 126/426 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SON | c.6325T>C p.C2109R | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA31D3 | c.2265G>C p.E755D | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SPTBN4 | c.3692T>A p.V1231E | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- STX2 | c.731A>C p.E244A | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- TAF5L | c.1489T>G p.L497V | Missense Mutation (SNP) | VAF 102/367 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TARM1 | c.367C>A p.L123I (on ENST00000616041 / NM_001330650.1; = p.L115I on NM_001135686.3) | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBCK | c.730G>A p.E244K (on ENST00000273980 / NM_001163436.4; = p.E181K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TBKBP1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TICRR | c.1823T>C p.I608T | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- TMEM132D | c.3032G>T p.S1011I | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TRIM72 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.864); called by muse, mutect2
- VWC2L | c.357C>A p.H119Q | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- WIPI1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 89/493 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WTIP | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 76/263 reads (29%) | called by muse, mutect2, varscan2
- ZBED6 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 12/454 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ARSF | c.900C>T p.D300= | Silent (SNP) | VAF 87/230 reads (38%) | catalogued as rs190353824; called by muse, mutect2, varscan2
- CAPN11 | c.2197C>T p.L733= | Silent (SNP) | VAF 74/378 reads (20%) | called by muse, varscan2
- CEP97 | c.1389T>C p.S463= | Silent (SNP) | VAF 100/261 reads (38%) | called by muse, mutect2, varscan2
- CRAT | c.363C>T p.G121= | Silent (SNP) | VAF 68/274 reads (25%) | catalogued as rs572976140; called by muse, mutect2, varscan2
- DST | c.17019G>C p.V5673= (on ENST00000361203 / NM_001374722.1; = p.V3370= on NM_015548.5) | Silent (SNP) | VAF 78/415 reads (19%) | called by muse, mutect2, varscan2
- ECSIT | c.1173C>T p.F391= | Silent (SNP) | VAF 132/315 reads (42%) | called by muse, mutect2, varscan2
- FMN2 | c.2781C>T p.P927= | Silent (SNP) | VAF 101/369 reads (27%) | catalogued as rs1163533476, COSV60417437, COSV60455856; called by muse, mutect2, varscan2
- FRYL | c.4695G>A p.E1565= | Silent (SNP) | VAF 95/256 reads (37%) | catalogued as rs745965446; called by muse, mutect2, varscan2
- GABRP | c.1062C>T p.I354= | Silent (SNP) | VAF 58/192 reads (30%) | called by muse, mutect2, varscan2
- GJB2 | c.228A>G p.L76= | Silent (SNP) | VAF 651/735 reads (89%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.798A>G p.G266= | Silent (SNP) | VAF 226/462 reads (49%) | called by muse, mutect2
- KRTAP13-3 | c.273T>G p.S91= | Silent (SNP) | VAF 142/512 reads (28%) | catalogued as COSV61879462, COSV61879897, COSV61880010; called by muse, mutect2, varscan2
- LAYN | c.390C>A p.G130= (on ENST00000375615 / NM_001258390.1; = p.G122= on NM_178834.5) | Silent (SNP) | VAF 64/245 reads (26%) | called by muse, mutect2, varscan2
- LOXHD1 | c.867C>T p.G289= | Silent (SNP) | VAF 84/245 reads (34%) | catalogued as rs748490817, COSV59671941; called by muse, mutect2, varscan2
- MDGA1 | c.285C>T p.I95= | Silent (SNP) | VAF 99/478 reads (21%) | catalogued as rs774778184; called by muse, mutect2, varscan2
- MDGA2 | c.294T>G p.V98= | Silent (SNP) | VAF 39/206 reads (19%) | called by muse, mutect2, varscan2
- MESP2 | c.21G>A p.P7= | Silent (SNP) | VAF 69/298 reads (23%) | called by muse, mutect2, varscan2
- MORC1 | c.1077C>T p.N359= | Silent (SNP) | VAF 67/223 reads (30%) | catalogued as rs369056513, COSV99225530; called by muse, mutect2, varscan2
- MRC1 | c.2163C>T p.S721= | Silent (SNP) | VAF 91/313 reads (29%) | called by muse, mutect2, varscan2
- MYBPC1 | c.3399A>G p.K1133= (on ENST00000550270 / NM_206820.2; = p.K1140= on NM_002465.4) | Silent (SNP) | VAF 14/167 reads (8%) | called by muse, mutect2
- MYH6 | c.1491G>T p.L497= | Silent (SNP) | VAF 59/369 reads (16%) | called by muse, mutect2, varscan2
- NFATC2 | c.534C>T p.F178= | Silent (SNP) | VAF 108/423 reads (26%) | catalogued as COSV65356929; called by muse, mutect2, varscan2
- PALD1 | c.1809C>T p.C603= | Silent (SNP) | VAF 86/303 reads (28%) | catalogued as rs1163313217, COSV99698484; called by muse, mutect2, varscan2
- PCARE | c.3609G>A p.P1203= | Silent (SNP) | VAF 107/441 reads (24%) | catalogued as rs375163820; ClinVar: likely benign; called by muse, mutect2, varscan2
- RIMBP2 | c.870C>T p.D290= | Silent (SNP) | VAF 104/313 reads (33%) | catalogued as rs372032522; called by muse, mutect2, varscan2
- RYR1 | c.693C>A p.T231= | Silent (SNP) | VAF 71/270 reads (26%) | catalogued as rs960734552; called by muse, mutect2, varscan2
- SIM1 | c.606C>T p.D202= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as rs1180669166, COSV99493010; called by muse, mutect2, varscan2
- SLC6A4 | c.1458C>T p.A486= | Silent (SNP) | VAF 78/277 reads (28%) | called by muse, mutect2, varscan2
- STT3B | c.1857G>A p.T619= | Silent (SNP) | VAF 65/219 reads (30%) | catalogued as rs539276584, COSV99854231; called by muse, mutect2, varscan2
- TAGLN | c.120T>C p.P40= | Silent (SNP) | VAF 109/362 reads (30%) | called by muse, mutect2, varscan2
- TMEM201 | c.1221C>T p.H407= | Silent (SNP) | VAF 238/381 reads (62%) | catalogued as rs1051912357; called by muse, mutect2, varscan2
- TMEM271 | c.183C>T p.G61= | Silent (SNP) | VAF 88/324 reads (27%) | called by muse, mutect2
- TTC30B | c.883C>T p.L295= | Silent (SNP) | VAF 100/409 reads (24%) | catalogued as rs762116116; called by muse, mutect2, varscan2
- VASH2 | c.294C>G p.V98= | Silent (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
- ZNF331 | c.162G>A p.K54= | Silent (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- ZNF737 | c.1209C>T p.G403= | Silent (SNP) | VAF 90/283 reads (32%) | catalogued as rs373070943; called by muse, mutect2, varscan2
- BRD2 | c.-1123G>A | 5'UTR (SNP) | VAF 92/480 reads (19%) | called by muse, mutect2, varscan2
- HTR2C | c.-1C>A | 5'UTR (SNP) | VAF 74/185 reads (40%) | called by muse, mutect2, varscan2
- KCNK10 | c.38-7212G>A | Intron (SNP) | VAF 104/371 reads (28%) | called by muse, mutect2, varscan2
